Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AE2I, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AE2I-TTP1-A (Primary Tumor).

[page 1 of 16]
RUN DATE: [REDACTED] +8 Laboratory Specimen Inquiry PAGE 1
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

Name: [REDACTED] Age/Sex: 56/F Attend DX: [REDACTED]
Acct#: [REDACTED] -2 Facil: [REDACTED] Location: [REDACTED]
Reg: [REDACTED] Unit#: [REDACTED] Date of Surgery: [REDACTED]

App# [REDACTED] Submitted: [REDACTED] -1 Received: [REDACTED] +0

COPIES TO:

★ Initial Path report

DISTAL ESOPHAGEAL/GE JUNCTION MASS BIOPSIES, 8:
POORLY DIFFERENTIATED ADENOCARCINOMA DEMONSTRATING CDX-2 NUCLEAR POSITIVITY
CONSISTENT WITH GASTROINTESTINAL PRIMARY. SEE COMMENT.

COMMENT:

The submitted specimen shows a poorly differentiated adenocarcinoma with features consistent with gastrointestinal primary. Most likely this represents either adenocarcinoma of the distal esophagus or adenocarcinoma arising from the upper aspect of the stomach. Differentiation between these two is not possible.

The presence of CDX-2 positivity is indicative of a gastrointestinal origin for the tumor. This, plus the negative results for estrogen receptor and progesterone receptor immunohistochemical stains essentially rules out the possibility of a breast primary.

Careful clinical correlation and follow-up are both highly recommended.

As part of the quality assurance program of [REDACTED] this case has been reviewed by an additional departmental pathologist who concurs with the above diagnosis.

Case discussed with [REDACTED]

TISSUES:

Esophagus - Distal esophagus/GE junction mass biopsy

Patient

DOB: [REDACTED] 56 yrs 93 Uni
Discharge Date: [REDACTED] Phone: [REDACTED]

[page 2 of 16]
RUN DATE:
RUN TIME:
RUN USER:

+8

Laboratory
Specimen Inquiry

PAGE 2

SPEC #:

PATIENT:

(Continued)

CLINICAL HISTORY:
Abdominal pain.

GROSS EXAMINATION:

The specimen is received in formalin, labeled distal esophagus/GE junction mass and consists of eight tan and roughened tissue fragments from 0.1 to 0.4 cm. All in one cassette.

MICROSCOPIC EXAMINATION:

Sections show portions of necrotic tissue associated with portions of benign squamous membrane and small fragments of gastric cardiac-type mucosa. Within the specimen there are multiple large biopsy specimens showing poorly differentiated adenocarcinoma with a minimal cribriform background pattern.

A limited number of immunohistochemical stains are performed with results as listed:

Monoclonal Antibody/Clone	Result	Pattern/Comment
CK7	Rare tumor cells positive.	Strong granular cytoplasmic staining.
CK20	Tumor cells negative.	
CDX-2	Tumor nuclei positive.	Diffuse intermediate nuclear staining.
Estrogen receptor/ SP-1	Tumor nuclei negative.	
progesterone receptor/ PgR636	Tumor nuclei negative.	

NOTE:

The immunostain(s) performed on this case were developed and the performance characteristics determined by the . The test(s) have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. The test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

FINAL REPORT dictated & authenticated by:
Signed out:

Patient:

DOB:

Admit:

79

Discharge Date:

Phone:

[page 3 of 16]
RUN DATE: [REDACTED] +8 Laboratory Specimen Inquiry PAGE 1
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

Name: [REDACTED] Age/Sex: 55/F Attend DX: [REDACTED]
Acct#: [REDACTED] Location: [REDACTED]
Reg: [REDACTED] Date of Surgery: [REDACTED]

Spec # [REDACTED] Submitted: [REDACTED] Received: [REDACTED] +0

COPIES TO:
[REDACTED] [REDACTED] [REDACTED]

DISTAL ESOPHAGEAL/GE JUNCTION MASS BIOPSIES, 8:
POORLY DIFFERENTIATED ADENOCARCINOMA DEMONSTRATING CDX-2 NUCLEAR POSITIVITY
CONSISTENT WITH GASTROINTESTINAL PRIMARY. SEE COMMENT.

COMMENT:

The submitted specimen shows a poorly differentiated adenocarcinoma with features consistent with gastrointestinal primary. Most likely this represents either adenocarcinoma of the distal esophagus or adenocarcinoma arising from the upper aspect of the stomach. Differentiation between these two is not possible.

The presence of CDX-2 positivity is indicative of a gastrointestinal origin for the tumor. This, plus the negative results for estrogen receptor and progesterone receptor immunohistochemical stains essentially rules out the possibility of a breast primary.

Careful clinical correlation and follow-up are both highly recommended.

As part of the quality assurance program of [REDACTED] this case has been reviewed by an additional departmental pathologist who concurs with the above diagnosis.

Case discussed with [REDACTED]

TISSUES:

Esophagus - Distal esophagus/GE junction mass biopsy

DOB: [REDACTED]
Discharge Date: [REDACTED] Phone: [REDACTED]

[page 4 of 16]
RUN DATE: [REDACTED] +8 Laboratory PAGE 2
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

SPEC: [REDACTED] PATIENT: [REDACTED] (Continued)

CLINICAL HISTORY:
Abdominal pain

GROSS EXAMINATION:

The specimen is received in formalin, labeled [REDACTED] distal esophagus/GE junction mass and consists of eight tan and roughened tissue fragments from 0.1 to 0.4 cm. All in one cassette.

MICROSCOPIC EXAMINATION:

Sections show portions of necrotic tissue associated with portions of benign squamous membrane and small fragments of gastric cardiac-type mucosa. Within the specimen there are multiple large biopsy specimens showing poorly differentiated adenocarcinoma with a minimal cribriform background pattern.

A limited number of immunohistochemical stains are performed with results as listed:

Monoclonal Antibody/Clone	Result	Pattern/Comment
CK7	Rare tumor cells positive.	Strong granular cytoplasmic staining.
CK20	Tumor cells negative.	
CDX-2	Tumor nuclei positive.	Diffuse intermediate nuclear staining.
Estrogen receptor/ SP-1	Tumor nuclei negative.	
Progesterone receptor/ PgR636	Tumor nuclei negative.	

NOTE:

The immunostain(s) performed on this case were developed and the performance characteristics determined by the [REDACTED]. The test(s) have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. The test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Patient

DOB:

Asst.

Unit

Discharge Date:

Phone:

[page 5 of 16]
PATIENT
DATE OF BIRTH: [REDACTED]
AGE: 55 GENDER: F
RECEIVED: [REDACTED] +21

HER2 FLUORESCENCE IN SITU HYBRIDIZATION REPORT

DIAGNOSIS

Distal esophageal/GE junction mass: Carcinoma

NEGATIVE for HER2 gene amplification by FISH

(Procedure Date: [REDACTED] -1)
HER2:CEP17 Ratio [REDACTED]
Number of tiles counted: 529
HER2 (SpectrumOrange) 3.5 mean signals per tile
CEP17 (SpectrumGreen) 2.9 mean signals per tile

MATERIAL RECEIVED

A1 = [REDACTED], 1 Block +21
Fixative: Formalin
Duration of fixation >6 and <48 hours?: Not provided on requisition*

CLIENT REQUEST/CLINICAL HISTORY

HER2 by FISH (if equivocal, IHC will be performed)

METHODOLOGY

Methods: Deparaffinized sections of tissue, following pretreatment, are incubated with PathVysion™ HER2 probe kit (Abbott Molecular, Chicago, IL) containing 2 separate probes: a locus-specific HER2 gene probe (17p11.2-q12) and a reference chromosome 17 centromere probe (CEP17; 17p11.1-q11.1). Morphometric image analysis is performed using a MetaSystems™ platform and Metafer 4™ application software. The HER2 and CEP17 signals are counted per tile/nucleus and the HER2:CEP17 ratio is calculated. **FISH Scoring:** Results are scored using criteria in the published trastuzumab clinical trials of gastric cancer: positive (HER2:CEP17 ratio ≥ 2.0), negative (HER2:CEP17 ratio <2.0). **Test Validation:** The test methodology employed in this laboratory has demonstrated an extremely high concordance rate (95%) between IHC and FISH. **Quality Assurance:** [REDACTED] has in place a quality assurance program for HER2 FISH, which includes daily controls (cell lines and tissues), Levy-Jennings analysis of HER2 controls, and ongoing concordance studies between IHC and FISH, to ensure high levels of interobserver and methodology concordance. **References:** Bang Y-J et al. *Lancet* 376:687-97, 2010; Hoffman M et al. *Histopathol* 52:797-805, 2008. [REDACTED] HER2 validation and ongoing monitoring of IHC and FISH assays demonstrate extremely high concordance (>95%) that is independent of the reported duration of fixation.]

* Electronically signed [REDACTED]

Per [REDACTED] regulations, the pathologist's signature above indicates that this case has been reviewed and the diagnosis made or confirmed by said pathologist.

Note: Some of the tests reported here may have been developed and performance characteristics determined by [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). However, the FDA has determined that such clearance or approval is not necessary. Pursuant to the requirements of CLIA, this laboratory has established and verified the accuracy and precision of all tests, and additional information about these tests is available upon request. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 6 of 16]
Patient:

DOB:

Site:

Ref. Prov:

Add. Providers:

EMPI:

PT/MOD:

Exam:

Visit/Acct: /

MRN:

Room/Ber

EXAM DATE

-2

Contrast/Isotope:

PROCEDURE: CT CHEST AND ABDOMEN WITH INTRAVENOUS CONTRAST

COMPARISON: None.

INDICATIONS: Second opinion read. Please comment on porta hepatis lymph nodes. History of esophageal cancer.

TECHNIQUE: CT scan of the chest and abdomen was performed with non-ionic intravenous contrast.

FINDINGS:

NECK BASE: No supraclavicular lymphadenopathy. There is a 5 mm low attenuating nodule in the left thyroid lobe which does not meet criteria for further evaluation with ultrasound due to its small size.

LUNGS: There is no lung mass. No discrete pulmonary nodules are identified though the patient was expiratory when scanned and low lung volumes may decrease sensitivity for detection of small pulmonary nodules.

AORTA/VASCULAR: Normal caliber main pulmonary artery. Normal caliber thoracoabdominal aorta with overall mild calcific atherosclerosis.

HILA/MEDIASTINUM: There is an irregular distal esophageal mass which appears to involve the gastroesophageal junction. There is no mediastinal or hilar lymphadenopathy by size criteria.

CARDIAC: Normal.

PLEURA: No pneumothorax or pleural effusion.

CHEST WALL/AXILLA: No chest wall mass or axillary lymphadenopathy.

LIVER: There are numerous hypoenhancing liver lesions in both the right and left lobes compatible with metastases. Rep. examples measure 1.5 x 1.3 cm in the right hepatic lobe and 1.6 x 1.3 cm at the junction of the right and left lobes near the liver dome.

BILIARY: Status post cholecystectomy with no biliary ductal dilation.

PANCREAS: Normal.

SPLEEN: Normal.

KIDNEYS: Normal.

ADRENALS: The right adrenal is normal. There is a 4.5 x 3.0 cm heterogeneously enhancing left adrenal nodule which measures greater than 10 Hounsfield units in density and is compatible with a metastasis.

RETROPERITONEUM: A few enlarged and heterogeneously enhancing gastrohepatic ligament lymph nodes are consistent with nodal metastases. The 2 largest lymph nodes measure 1.8 cm and 1.2 cm short axis respectively whereas another gastrohepatic ligament node measuring 0.8 cm short axis is also suspicious. There is also a prominent portacaval lymph node measuring 1.4 cm short axis. Another portal caval lymph node measures 0.7 cm short axis.

[page 7 of 16]
Continued Report - Page 2 of 2

Patient: [REDACTED]
DOB: [REDACTED]
Site: [REDACTED] EMPI: [REDACTED]
Ref. Prov: [REDACTED] PT/MD: [REDACTED] Visit/Acct: /
Add. Providers: [REDACTED] Exam: [REDACTED] MRN: [REDACTED]
Room/Bec [REDACTED]

EXAM DATE: [REDACTED] -2 Contrast/Isotope:

BOWEL/MESENTERY: There is no ascites, intra-abdominal fluid collection, or free intraperitoneal air. No evidence of peritoneal carcinomatosis. No evidence of a bowel obstruction or other acute process involving bowel.

ABDOMINAL WALL: Normal.

PELVIC ORGANS: Status post hysterectomy. No adnexal mass is identified. The bladder is within normal limits.

BONES: No destructive osseous lesions are identified.

OTHER: Negative.

CONCLUSION: Irregular esophageal mass consistent with esophageal carcinoma. There are multiple hepatic metastases and a left adrenal metastasis. Enlarged lymph nodes at the gastrohepatic ligament are consistent with nodal metastases. An additional prominent portocaval lymph node measuring 1.4 cm short axis (not pathologically enlarged for this nodal station) and another small portocaval lymph node measuring 0.7 cm short axis are of uncertain significance and can be reassessed on followup exams.

[page 8 of 16]
Results

CT SCAN CHEST, ABDOMEN AND PELVIS (Order

PACS Images

Show images for

Result Information

+87 Status Final result [REDACTED] Provider Status Reviewed

Result Narrative

[REDACTED] Restaging esophageal cancer.

[REDACTED] Restaging esophageal cancer.

CT CHEST, ABDOMEN, AND PELVIS, with contrast, :

TECHNIQUE: Multislice spiral CT, with axial sections through the chest, abdomen, and pelvis following oral contrast administration and during intravenous administration of 125 cc's Optiray 320 non-ionic contrast.

COMPARISON: No prior studies available for comparison.

CT CHEST FINDINGS:

Mediastinum and hilar areas: Unremarkable with no enlarged lymph nodes. There is some thickening of the distal esophagus that may reflect the patient's esophageal cancer.

Lungs, bronchi, and pleural spaces: Unremarkable with no lung nodules and no pleural effusion

Chest wall: Unremarkable

CT ABDOMEN AND PELVIS FINDINGS:

Liver and spleen: There are multiple low density lesions throughout the liver consistent with metastases. These are all under 12 mm in diameter.

Gall bladder, biliary tract, and pancreas: Unremarkable with no gall stones and no biliary tract dilation seen.

Aorta and lymph nodes: There is a perigastric lymph node measuring 10 x 14 mm on image number 98. Several porta hepatis lymph nodes are seen on image number 109 measure in 7 x 50 mm and 8 x 15 mm.

Bowel and peritoneal spaces: Unremarkable

Adrenals and kidneys: Low-density left adrenal lesion is seen measuring 10 x 26 mm with Hounsfield unit density of 26. This could reflect a metastasis. Right adrenal and both kidneys appear unremarkable.

Urinary bladder: Unremarkable

Abdominal wall: Unremarkable

Result Impression

IMPRESSION:

There are numerous small hepatic metastases.

[page 9 of 16]
Left adrenal lesion is suspicious for metastasis.

There are several prominent porta hepatis lymph nodes and a right perigastric lymph node

Thickening of distal esophagus which could be reflective of the patient's carcinoma.

Reading Radiologist

Patient Release Status:

This result is viewable by the patient in

By:

Encounter

View Encounter

Collection Information

Collected:

Resulting
Agency:

+87

Lab and Collection

CT SCAN CHEST, ABDOMEN AND PELVIS (Order
Information

Lab and Collection
+77

Result History

CT SCAN CHEST, ABDOMEN AND PELVIS (Order
Report

Order Result History
+77

Order

CT SCAN CHEST, ABDOMEN AND PELVIS

PACS Images

Show images for

Order Information

Order Date

Visit Date

Ordering User

Pa

Patient Name

Sex

DOB

SSN

Female

Code Status
Not on file

Order Providers

Authorizing Provider

Encounter Provider

[page 10 of 16]
NPI: [REDACTED]

Comments

[REDACTED] Restaging esophageal cancer.

[REDACTED] Restaging esophageal cancer.

Detailed Information

Priority and Order Details

Collection Information

Reference Links

What if I can't find the Reason for
Exam? Or other questions.

Encounter

View Encounter

[page 11 of 16]
Radiology Consultation

Patient Name: [REDACTED]

Home Loc: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Sex: F

Pt Status: O

Pt Home Phone: [REDACTED]

Pt Work Phone: [REDACTED]

Exam: (SIL) MRBIRNYESDTM - MR BRAIN W/WO

Accession: [REDACTED] +93

Completed: [REDACTED] Fluoro time: 0

Signs & Symptoms: T/U brain metastasis

History: T/U brain metastasis

Primary Care Provider: [REDACTED]

Requesting Provider: [REDACTED]

Attending Provider: [REDACTED]

Report To Provider: [REDACTED]

Comments: [REDACTED]

BRAIN MRI WITH GAD

Please call patient to schedule. Dr wants done before end of year.

EXAMINATION: MR scan of the brain

COMPARISON: [REDACTED] +35

REASON: Follow-up intracranial metastatic disease

TECHNIQUE:

Pre-contrast axial and sagittal T1, axial diffusion, axial flair, axial T2. Postcontrast axial, coronal and sagittal T1-weighted images. 15 cc Magnevist

FINDINGS:

Previous parietal ring enhancing lesion measuring nearly 10 mm appears as a solid region of enhancement measuring 5.6 mm. Left occipitoparietal enhancing nodule measuring 8.8 mm today measures 5 mm. Comparison of flair pulse sequences demonstrating brain substance to approximate the inset table. Previously seen left occipitoparietal edema has resolved.

IMPRESSION:

Resolution of peri-lesion edema.

Decrease in lesion in diameter

[page 12 of 16]
Patient Name:

Home Loc:

MRN:

DOB:

Sex: F

Pt Status: O

Pt Home Phone:

Pt Work Phone:

Exam: (SIL) MRBRNCYESDTM - MR.BRAIN W/VO

Accession:

Completed:

Fluoro.time:

0

Signs & Symptoms: no brain metastasis

History: F/U brain metastasis

[page 13 of 16]
Patient:

DOB:

Site:

Ref. Prov:

Add. Providers:

EMPI:

PT/MOD:

Exam:

Visit/Acct:

MRN:

Room/Bed:

EXAM DATE:

+1413

Contrast/Isotope: 150cc isvoue 300 SD/0cc discarded

PROCEDURE: CT CHEST, ABDOMEN, AND PELVIS WITH CONTRAST

COMPARISON: CT, CT PNL CHEST/ABD/PELVIS WITH CONTRAST

+1218

INDICATIONS: Stage 4 Bladder Cancer. Restaging.

PQRS QUALITY INFORMATION:

EXAM COUNT: 3 CT exams and 0 NM Myocardial Perfusion exams in past 12 months.

DATA AVAILABILITY: Dicom format image data is available to non-affiliated external entities on secure, media free, reciprocally searchable basis for 12 month period of time after the study.

DATA SEARCH: A search was conducted for prior patient CT exams performed at an external facility within 12 months prior to the imaging study being performed, and is available through a secure, authorized, media free, shared archive.

CT DOSE REGISTRY: CT study data has not been reported to a CT Radiation Dose Index Registry as CT system is not capable of sending dose information.

Total Dose Length Product (DLP in mGy-cm): 932.7

TECHNIQUE: CT scan of the chest, abdomen, and pelvis was performed with non-ionic intravenous contrast.

FINDINGS:

NECK BASE: Normal.

LUNGS: Normal.

AORTA/VASCULAR: Moderate atherosclerotic calcification is present.

HILA/MEDIASTINUM: Small hiatal hernia is present. The wall thickening of the small hiatal hernia is less prominent.

CARDIAC: Normal.

PLEURA: Normal.

CHEST WALL/AXILLA: Normal.

LIVER: Small hypodense nodules in the liver are stable.

BILIARY: Normal.

PANCREAS: Normal.

SPLEEN: Normal.

KIDNEYS: 2 cm right renal cyst is present.

ADRENALS: Normal.

RETROPERITONEUM: Normal.

BOWEL/MESENTERY: Normal.

ABDOMINAL WALL: Small fat containing umbilical hernia is present.

PELVIC ORGANS: Status post hysterectomy.

BONES: Moderate L4-5 disc degenerative changes are present.

OTHER: Negative.

CONCLUSION: Stable appearance of the chest, abdomen and pelvis, no evidence of metastatic disease.

[page 14 of 16]
Continued Report - Page 2 of 2

Patient:

DOB:

Site:

Ref. Prov:

Add. Providers:

EMPI:

PT/MOD: Out/CT

Exam:

Visit/Acct

MRN:

Room/Bed:

+1413

EXAM DATE:

Contrast/isotope: 150cc Isovue 300 SD/0cc discarded

Approved by:

[page 15 of 16]
Patient:

DOB:

Site:

Ref. Prov:

Add. Providers:

EMPI:

PT/MOD:

Exam:

Visit/Acct:

MRN:

Room/Bed:

+1413

EXAM DATE

Contrast/Isotope: 8cc Gadavist MD

PROCEDURE: MRI BRAIN WITHOUT AND WITH INTRAVENOUS CONTRAST

COMPARISON: MR, MRI BRAIN WOW CONTRAST,
+1235

INDICATIONS: Restaging. Stage 4 esophageal cancer,

TECHNIQUE: Pre-contrast images of the brain were obtained initially, followed by contrast enhanced MRI. Detailed pulse sequence parameters are listed on

FINDINGS:

GENERAL:

Status post left craniotomy and resection of left parietal lobe metastatic lesion. The postoperative cavity has decreased in size and there has been a pronounced degree of resolution of the T2 weight signal abnormality since the prior study. In addition the postcontrast images demonstrates resolution of the majority of the predominantly linear enhancement at the margins of the operative cavity. Apparent enhancement some distance from the anterior margin of the resection cavity is felt to represent postsurgical artifact

VENTRICLES:

Normal in size and morphology.

BRAIN:

In addition to the findings described above, there are numerous areas of nonspecific, nonenhancing T2 hyperintensity within the supratentorial white matter. These are unchanged as the prior examination and likely represent manifestations of chronic microvascular disease. Cerebellar tonsils are not low-lying.

SKULL/SCALP:

Unremarkable.

MASTOIDS:

Visualized portions are well aerated.

ORBITS:

Normal.

SINUSES:

Limited views demonstrate no significant mucosal thickening or fluid.

OTHER:

Expected arterial and dural venous flow voids are present.

CONCLUSION: Interval significant resolution of widespread signal abnormality involving the left parietal lobe in a patient who is undergone prior left parietal craniotomy and resection of a metastatic deposit.

No residual or recurrent mass at the operative site.

There has also been resolution of the majority of the predominantly linear enhancement at the margins of the operative cavity, consistent with resolving postoperative change.

No new intracranial lesions

[page 16 of 16]
Continued Report - Page 2 of 2

Patient:

DOB:

Site:

Ref. Prov:

Add. Providers:

EMPI:

PT/MOD:

Exam:

Visit/Acct:

MRN:

Room/Bed:

+1413

EXAM DATE:

Contrast/Isotope: 8cc Gadavist MD

Source: NCI Genomic Data Commons file abaa77db-0939-4eba-af01-380c65b2b6e0 (ER0282 ER-AE2I Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).